Surgical pathology report (de-identified scan), TCGA case TCGA-EU-5907, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EU-5907-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

ADDENDUM REPORT

This addendum is issued to reflect a discussion with the surgeon, [REDACTED] about the specimen. Initially, there was thought to be renal cell carcinoma at the renal vein margin as it appeared to bulge out of the vein. However, in discussion with [REDACTED] grossly and clinically the carcinoma appears to be well free of the surgical margin. Sometimes in fixation and manipulation of the specimen the vein can retract leading to the appearance of tumor at the margin. Given the discussion and initial findings in this case, this appears to be the case here. Therefore, this is interpreted as no positivity at the vein margin.

ADDENDUM DIAGNOSIS:

RIGHT KIDNEY, RADICAL NEPHRECTOMY WITH PARTIAL ADRENAL GLAND EXCISION

- Invasive conventional clear cell carcinoma, Fuhrman grade 3.
- **Tumor invasion into renal vein, renal vein margin negative for tumor.**
- Benign adrenal gland.

SPECIMEN

A. KIDNEY - 1. Right kidney

CLINICAL INFORMATION

Renal cell carcinoma, right renal thrombus

GROSS DESCRIPTION

Received in formalin labeled [REDACTED] "right kidney" is a 522 gm, 18 x 11 x 5 cm specimen which includes a 12.5 x 7 x 4 cm kidney and surrounding soft yellow fatty perinephric fat. The specimen was previously opened for the Genome study. A portion of adrenal gland is seen in the perinephric fat just superior to the renal vein and is 1 x 0.5 x 0.5 cm. The adrenal gland is grossly uninvolved by tumor. The

[page 2 of 3]
[REDACTED]

perinephric fat and surgical margin are inked in black, and the ureteral, renal artery, and renal vein margins are taken. The ureter and renal artery are grossly uninvolved by tumor. The renal vein has tumor bulging out of the vein at the resection margin. Hilar lymph nodes are not identified. The previously bivalved kidney shows an orange, lobular well-circumscribed tumor which is 8 x 5 x 3.8 cm. The tumor grossly invades into the pelvis and is located predominantly in the inferior pole of the kidney. The remainder of the kidney is tan with a normal corticomedullary junction.

SLIDE KEY:

- A1 – renal artery, and renal vein margins
- A2 – additional section of renal vein with tumor at the margin
- A3 – tumor invading the pelvis
- A4 – tumor adjacent to normal kidney
- A5 – normal kidney
- A6 – tumor adjacent to renal vein tributary
- A7 – tumor
- A8 – tumor adjacent to closest inked perinephric fat margin
- A9 – adrenal gland and adjacent kidney
- A10 - ureter margin
- A11-12 – additional sections of tumor
- [REDACTED]

MICROSCOPIC DESCRIPTION

Surgical Pathology Cancer Case Summary, Kidney

SPECIMEN TYPE: Right nephrectomy with partial resection of adrenal gland.

TUMOR SITE: Inferior pole.

TUMOR SIZE: 8 x 5 x 3.8 cm.

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney.

HISTOLOGIC TYPE: Conventional clear cell renal cell carcinoma. The possibility of a chromophobe carcinoma was considered; therefore, a Hale's colloidal iron stain and immunostains were performed with appropriately reactive controls. The Hale's colloidal iron showed positivity in approximately 5% of the tumor cells. The tumor cells were negative for E-cadherin, CD117, and CK7. There is positivity with vimentin and CD10. The immunohistochemical profile and relative lack of significant positivity with Hale's colloidal iron is consistent with a conventional renal cell carcinoma.

HISTOLOGIC GRADE: Grade 3. Nuclei are irregular, approximately 20 microns; nucleoli are large and prominent. Most of the tumor shows grade 2 nuclei; however, in several areas, entire fields show Fuhrman grade 3 nuclei.

EXTENT OF INVASION: T3a, tumor grossly extends into renal vein margins. There is no tumor at the soft tissue margins, ureteral, or arterial margin. However, tumor does appear to be present at the renal vein margin.

BLOOD/LYMPHATIC VESSEL INVASION: Absent.

ADRENAL GLAND: Uninvolved by tumor.

REGIONAL LYMPH NODES: None identified.

DISTANT METASTASIS: MX, cannot be assessed.

[REDACTED]

FINAL DIAGNOSIS

[REDACTED]

[page 3 of 3]
RIGHT KIDNEY, RADICAL NEPHRECTOMY WITH PARTIAL ADRENAL GLAND EXCISION

- Invasive conventional clear cell carcinoma, Fuhrman grade 3.
- Tumor invasion into renal vein with positivity at vein margin.
- Benign adrenal gland.
- Please see cancer case summary.

CPT CODES: 88307, 88313, 88342x5

Source: NCI Genomic Data Commons file b1aaedc0-e20b-446b-a4c4-6f1fccc59738 (TCGA-EU-5907.0A1D3E0F-0CC3-4139-9578-881D8B3879A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).